Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A5B8, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A5B8-01A (Primary Tumor).

Gross Description: There is a part of the esophagus up to 9x6 cm in size, with gray ulcerated tumor up to 6x4 cm in size. There is a part of the stomach up to 13x6 cm in size. Separately there is one paraesophageal lymph node.

Microscopic Description: Squamous cell carcinoma, keratinizing, G-1 (pT3). Chronic gastritis. One examined lymph node demonstrated follicular hyperplasia.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Adventitia, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Esophagectomy

Tumor site: Esophagus

Tumor size: 4 x 0 x 6 cm

Histologic type: Squamous cell carcinoma, keratinizing

Histologic grade: Well differentiated

Tumor extent: Adventitia

Lymph nodes: 0/1 positive for metastasis (Paraesophageal nodes 0/1)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

Carcinoma, squamous cell,
Keratinizing, NOS 8071/3
Site: Esophagus, C15.9

12/18/12

IP/VA Discrepancy		
Site Malignancy history		

Source: NCI Genomic Data Commons file 337ce0e2-be77-492f-94e7-050766bbdbd5 (TCGA-IG-A5B8.096C6D20-D3FA-4559-A59D-9E473482B1E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).